Somatic mutation profile of tumor specimen TCGA-BC-A10W-01A (aliquot TCGA-BC-A10W-01A-11D-A12Z-10) from TCGA case TCGA-BC-A10W, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G3; Age at diagnosis: 50.8 years (18,562 days).
Specimen TCGA-BC-A10W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 455be7f9-2227-4608-9971-24aa9f5b264b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BC-A10W-11A (Solid Tissue Normal), aliquot TCGA-BC-A10W-11A-11D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/831fb42a-8a8b-4d00-be0c-0ad4a5281247

The open-access MAF lists 113 somatic variants for this specimen: 84 protein-altering or splice-affecting, 28 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 28, Splice Site 4, Nonsense Mutation 4, Frame Shift Ins 3, Frame Shift Del 2, Splice Region 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AANAT | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs770524125, COSV51686543; called by mutect2, varscan2
- ABCC4 | c.382T>G p.S128A | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.102); catalogued as COSV65318708; called by muse, mutect2, varscan2
- ACE | c.448A>G p.I150V | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.146); catalogued as COSV52027529; called by muse, mutect2, varscan2
- ADAMTS19 | c.3382C>A p.H1128N | Missense Mutation (SNP) | VAF 211/461 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV50802680; called by muse, mutect2, varscan2
- AFF1 | c.1700C>A p.S567Y | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV57124722; called by muse, mutect2, varscan2
- AK2 | c.398G>A p.R133Q (on ENST00000354858; = p.R175Q on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs1243124080, CM1313754, CM136235, COSV61470414; called by muse, mutect2, varscan2
- ALPK2 | c.1282G>C p.G428R | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV64497528, COSV64497817; called by muse, mutect2
- ARID1A | c.1350G>A p.Q450= | Splice Region (SNP) | VAF 113/201 reads (56%) | catalogued as COSV61389842; called by muse, mutect2, varscan2
- ATM | c.2215G>T p.E739* | Nonsense Mutation (SNP) | VAF 41/109 reads (38%) | catalogued as COSV53777168; called by muse, mutect2, varscan2
- CCNB1 | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 83/264 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV56510661; called by muse, mutect2, varscan2
- CENPE | c.6896T>A p.V2299E | Missense Mutation (SNP) | VAF 84/220 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV54391156; called by muse, mutect2, varscan2
- CFAP299 | c.448dup p.R150Kfs*17 | Frame Shift Ins (INS) | VAF 61/209 reads (29%) | catalogued as rs761800837; called by mutect2, varscan2
- CNKSR1 | c.1511A>G p.Y504C (on ENST00000374253 / NM_001297647.2; = p.Y497C on NM_006314.3) | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58794820; called by muse, mutect2, varscan2
- COBLL1 | c.2003A>G p.N668S (on ENST00000392717; = p.N630S on NM_014900.5) | Missense Mutation (SNP) | VAF 214/607 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV52076826; called by muse, mutect2, varscan2
- COL11A1 | c.4208A>T p.K1403M | Missense Mutation (SNP) | VAF 56/376 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62198932; called by muse, mutect2, varscan2
- CPT1C | c.1174C>A p.Q392K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as COSV54922492; called by muse, mutect2, varscan2
- CTSK | c.130A>G p.I44V | Missense Mutation (SNP) | VAF 240/314 reads (76%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV55013960; called by muse, mutect2, varscan2
- CYP27C1 | c.299A>C p.Y100S | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.69); catalogued as COSV58868628; called by muse, mutect2, varscan2
- DBR1 | c.1516A>T p.T506S | Missense Mutation (SNP) | VAF 175/494 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV53431278; called by muse, mutect2, varscan2
- DXO | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1035710983, COSV61715187; called by muse, mutect2
- E2F6 | c.658A>G p.I220V | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs371114161; called by muse, mutect2, varscan2
- ELAPOR2 | c.749T>C p.L250P (on ENST00000450689 / NM_001142749.3; = p.L83P on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51892209; called by muse, mutect2
- EXTL3 | c.1198T>C p.C400R | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55040682; called by muse, mutect2
- FAM180A | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV58529412; called by muse, mutect2, varscan2
- FAM71D | c.501G>A p.W167* | Nonsense Mutation (SNP) | VAF 84/219 reads (38%) | catalogued as rs546523990, COSV61296718; called by muse, mutect2, varscan2
- FNDC3B | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 94/245 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.119); catalogued as COSV61037181; called by muse, mutect2, varscan2
- GPT | c.278A>T p.D93V | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.148); catalogued as COSV52954973; called by muse, mutect2
- GSDMD | c.1294T>A p.W432R | Missense Mutation (SNP) | VAF 86/124 reads (69%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV52798363; called by muse, varscan2
- HEG1 | c.3438G>C p.R1146S | Missense Mutation (SNP) | VAF 71/223 reads (32%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV60765875; called by muse, mutect2, varscan2
- HK2 | c.2054G>T p.C685F | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51872862; called by muse, mutect2, varscan2
- IAH1 | c.728T>G p.L243R | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as COSV60402008; called by muse, mutect2, varscan2
- ITGA10 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 20/476 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65197567, COSV65199314; called by muse, mutect2
- JAK2 | c.3203A>G p.D1068G | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.934); catalogued as COSV67680824; called by muse, mutect2, varscan2
- KCNB2 | c.1781T>A p.I594N | Missense Mutation (SNP) | VAF 85/120 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.724); catalogued as COSV73053141; called by muse, mutect2, varscan2
- KHDC3L | c.218T>A p.L73* | Nonsense Mutation (SNP) | VAF 36/91 reads (40%) | catalogued as COSV64869805; called by muse, mutect2, varscan2
- KIAA0586 | c.2447T>A p.V816D (on ENST00000619416 / NM_001244190.2; = p.V755D on NM_014749.5) | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.075); catalogued as COSV54183043; called by muse, mutect2, varscan2
- KIF19 | c.880A>C p.K294Q | Missense Mutation (SNP) | VAF 75/139 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.27); catalogued as COSV63430699; called by muse, mutect2, varscan2
- LCE1F | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 580/763 reads (76%) | SIFT tolerated, low confidence (0.78); PolyPhen probably damaging (0.932); catalogued as COSV57670334; called by muse, mutect2, varscan2
- LRP2 | c.10687G>A p.G3563S | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs745375377, COSV55576099; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MLH1 | c.605C>G p.A202G | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.185); catalogued as COSV51624869; called by muse, mutect2, varscan2
- MOCS3 | c.1177A>T p.I393F | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV54868047; called by muse, mutect2, varscan2
- MTMR4 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60204078; called by muse, mutect2, varscan2
- MUC16 | c.25265G>A p.S8422N | Missense Mutation (SNP) | VAF 68/115 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV67496273; called by muse, mutect2, varscan2
- MUSK | c.2581G>T p.E861* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV51897454, COSV99505267; called by muse, mutect2, varscan2
- MYH4 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 130/395 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55126989, COSV99702332; called by muse, mutect2, varscan2
- MYLIP | c.868C>A p.R290S | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62766564, COSV62767715; called by muse, mutect2, varscan2
- NEBL | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769728098, COSV65802410, COSV65806116; called by muse, mutect2, varscan2
- NELFE | c.461A>G p.E154G | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100952551; called by mutect2, varscan2
- NR3C2 | c.2450G>T p.R817I | Missense Mutation (SNP) | VAF 73/215 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100678585, COSV61000328; called by muse, mutect2, varscan2
- NYNRIN | c.842C>A p.A281E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV66845284; called by muse, mutect2, varscan2
- OGFOD3 | c.700-1G>T p.X234_splice | Splice Site (SNP) | VAF 18/80 reads (23%) | catalogued as COSV57343522; called by muse, mutect2, varscan2
- PDX1 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as rs1049166702, COSV66847150; called by muse, mutect2, varscan2
- PIKFYVE | c.5827G>T p.G1943W | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100009514; called by muse, mutect2, varscan2
- PIKFYVE | c.5828G>C p.G1943A | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as COSV100009516, COSV52238351; called by muse, mutect2
- PPP1R3B | c.689A>G p.Y230C | Missense Mutation (SNP) | VAF 172/449 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761789006, COSV60100318; called by muse, mutect2, varscan2
- PTPRN2 | c.2715G>T p.Q905H | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66104990; called by muse, mutect2, varscan2
- QRICH2 | c.2350G>A p.D784N | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as COSV53158198; called by muse, mutect2, varscan2
- RASSF1 | c.941G>C p.R314P (on ENST00000357043 / NM_170714.2; = p.R310P on NM_007182.5) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51701782; called by muse, mutect2
- RLN2 | c.484C>A p.Q162K | Missense Mutation (SNP) | VAF 100/290 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as COSV57731938; called by muse, mutect2, varscan2
- RPRD1B | c.593G>C p.R198P | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100987333, COSV65034154; called by muse, mutect2, varscan2
- SCN3A | c.1669C>A p.Q557K | Missense Mutation (SNP) | VAF 134/323 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); catalogued as COSV51825472, COSV99328957; called by muse, varscan2
- SNX15 | c.721T>A p.S241T | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV57248698; called by muse, mutect2, varscan2
- SOCS6 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV67547246; called by muse, mutect2, varscan2
- SPTLC2 | c.1094T>A p.L365Q | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV53643321; called by muse, mutect2, varscan2
- SRSF3 | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV59672143; called by muse, mutect2, varscan2
- TMEM64 | c.863T>C p.L288P | Missense Mutation (SNP) | VAF 47/273 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69128206; called by muse, mutect2, varscan2
- TMPRSS11B | c.584del p.A195Dfs*20 | Frame Shift Del (DEL) | VAF 65/232 reads (28%) | catalogued as COSV60293104; called by mutect2, pindel, varscan2
- TRIM22 | c.1355G>A p.G452D | Missense Mutation (SNP) | VAF 77/294 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV66091896; called by muse, mutect2, varscan2
- TRIOBP | c.2526T>A p.D842E | Missense Mutation (SNP) | VAF 92/233 reads (39%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as COSV60384787; called by muse, mutect2, varscan2
- TSEN34 | c.910C>G p.L304V | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV55477765; called by muse, mutect2
- TXNL1 | c.99-1G>T p.X33_splice | Splice Site (SNP) | VAF 68/211 reads (32%) | catalogued as COSV54181224; called by muse, mutect2, varscan2
- USHBP1 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs771253779, COSV53106374; called by muse, mutect2, varscan2
- USP40 | c.2192A>G p.D731G | Missense Mutation (SNP) | VAF 82/268 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV52488932; called by muse, mutect2, varscan2
- ZBED9 | c.1241C>G p.P414R | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); catalogued as COSV71729795; called by muse, mutect2
- ZFR | c.6T>G p.I2M | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); catalogued as COSV54058197; called by muse, mutect2, varscan2
- ZFYVE1 | c.2201A>G p.K734R | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs1315812826, COSV59613291; called by muse, mutect2, varscan2
- ZNF112 | c.1231G>A p.E411K (on ENST00000337401 / NM_001083335.2; = p.E405K on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV61622235; called by muse, mutect2, varscan2
- DNAJC13 | c.1450-20_1456del p.X484_splice | Splice Site (DEL) | VAF 17/144 reads (12%) | called by mutect2, pindel, varscan2
- GABARAP | c.40_60del p.R14_K20del | In Frame Del (DEL) | VAF 26/104 reads (25%) | called by mutect2, varscan2
- GABRG2 | c.1188del p.L396Ffs*36 (on ENST00000361925 / NM_001375343.1; = p.L356Ffs*36 on NM_000816.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 187/879 reads (21%) | called by mutect2, pindel, varscan2
- IGLV5-48 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- LEAP2 | c.102dup p.P35Afs*23 | Frame Shift Ins (INS) | VAF 53/136 reads (39%) | called by mutect2, pindel, varscan2
- NRBP2 | c.1077-6_1077-2dup p.X359_splice | Splice Site (INS) | VAF 20/96 reads (21%) | called by mutect2, varscan2
- PDZD9 | c.560dup p.H187Qfs*4 (on ENST00000424898 / NM_001363519.1; = p.H127Qfs*4 on NM_173806.4) | Frame Shift Ins (INS) | VAF 111/397 reads (28%) | called by mutect2, pindel, varscan2
- ADORA3 | c.771T>A p.G257= | Silent (SNP) | VAF 20/339 reads (6%) | catalogued as COSV53987046; called by muse, mutect2
- AFMID | c.183G>A p.K61= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as COSV59977694; called by muse, mutect2, varscan2
- ALOX12 | c.1095C>T p.H365= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV52352319; called by muse, mutect2, varscan2
- ASIP | c.256C>A p.R86= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV66588748; called by muse, mutect2, varscan2
- ECEL1 | c.2235G>T p.L745= | Silent (SNP) | VAF 44/88 reads (50%) | catalogued as COSV58814399; called by muse, mutect2, varscan2
- FIGN | c.1548G>T p.T516= | Silent (SNP) | VAF 50/134 reads (37%) | catalogued as COSV60772033; called by muse, mutect2, varscan2
- GABRG2 | c.1419G>A p.R473= (on ENST00000361925 / NM_001375343.1; = p.R433= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 183/663 reads (28%) | catalogued as COSV62722872; called by muse, mutect2, varscan2
- GRID2 | c.447T>G p.P149= | Silent (SNP) | VAF 50/136 reads (37%) | catalogued as COSV56271513; called by muse, mutect2
- GRM1 | c.2133A>T p.S711= | Silent (SNP) | VAF 68/185 reads (37%) | catalogued as COSV51364301; called by muse, mutect2, varscan2
- HAUS6 | c.1323T>C p.N441= | Silent (SNP) | VAF 158/446 reads (35%) | catalogued as COSV65840905; called by muse, varscan2
- KRT4 | c.1086C>A p.I362= | Silent (SNP) | VAF 40/250 reads (16%) | catalogued as COSV53409937; called by muse, mutect2, varscan2
- LIX1L | c.684G>A p.L228= | Silent (SNP) | VAF 69/499 reads (14%) | catalogued as COSV100811076, COSV63417313; called by muse, mutect2, varscan2
- MN1 | c.3138G>A p.S1046= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs1394727358, COSV56562549; called by muse, mutect2, varscan2
- MRC2 | c.3045A>T p.T1015= | Silent (SNP) | VAF 43/97 reads (44%) | catalogued as COSV57644934; called by muse, mutect2, varscan2
- NCOA6 | c.2643G>A p.T881= | Silent (SNP) | VAF 131/341 reads (38%) | catalogued as rs147990465; called by muse, mutect2, varscan2
- NOTCH2 | c.444C>T p.C148= | Silent (SNP) | VAF 373/549 reads (68%) | catalogued as rs587603360, COSV56707219; called by muse, mutect2, varscan2
- PNLIP | c.381C>T p.S127= | Silent (SNP) | VAF 59/111 reads (53%) | catalogued as COSV65040220, COSV65042060; called by muse, mutect2, varscan2
- PTPRU | c.3366C>T p.S1122= | Silent (SNP) | VAF 41/72 reads (57%) | catalogued as COSV60537045; called by muse, mutect2, varscan2
- RGL2 | c.1419C>G p.L473= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as COSV65842207; called by muse, mutect2, varscan2
- RIN3 | c.1302G>A p.Q434= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as COSV53656109; called by muse, mutect2, varscan2
- SLC9C2 | c.1185C>T p.L395= | Silent (SNP) | VAF 96/925 reads (10%) | catalogued as rs761843503, COSV62944593, COSV62949781; called by muse, mutect2, varscan2
- SPEN | c.8077C>T p.L2693= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV65367735; called by muse, mutect2
- SYNE2 | c.14067G>A p.V4689= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as COSV59971495; called by muse, mutect2, varscan2
- TCF19 | c.642G>T p.T214= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV52565116; called by mutect2, varscan2
- TCF21 | c.468G>A p.V156= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV52819734; called by muse, mutect2, varscan2
- UHRF2 | c.1305T>G p.R435= | Silent (SNP) | VAF 120/344 reads (35%) | catalogued as COSV99435979; called by muse, mutect2, varscan2
- WNK1 | c.6522A>C p.P2174= (on ENST00000315939 / NM_018979.4; = p.P1926= on NM_014823.3) | Silent (SNP) | VAF 55/129 reads (43%) | catalogued as COSV60046017; called by muse, mutect2, varscan2
- XPO1 | c.3081T>G p.G1027= | Silent (SNP) | VAF 51/172 reads (30%) | catalogued as COSV68947987; called by muse, mutect2, varscan2
- MZT2A | c.*2A>T | 3'UTR (SNP) | VAF 74/235 reads (31%) | catalogued as rs200640575, COSV100342188; called by muse, mutect2, varscan2
